Somatic mutation profile of tumor specimen 0DL6RZ from CCDI case PBBYTF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,598 days).
Specimen 0DL6RZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36b73172-8cd9-4bfb-a046-bb67710813de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL6RI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d8abf80-5056-4d80-a315-f54a22eae313

The open-access MAF lists 2 somatic variants for this specimen: 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HMGB1 | c.*85T>C | 3'UTR (SNP) | VAF 10/188 reads (5%) | catalogued as COSV100360835; called by muse, mutect2
- HNRNPU | c.1924+11T>C | Intron (SNP) | VAF 232/597 reads (39%) | called by muse, mutect2, varscan2
